Somatic mutation profile of tumor specimen ALCH-B1TH-TTP1-A (aliquot ALCH-B1TH-TTP1-A-1-0-D-A770-36) from ALCHEMIST case ALCH-B1TH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.0 years (24,825 days).
Specimen ALCH-B1TH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbd1ba73-e940-4118-8f2b-acff09914d6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1TH-NB1-A (Blood Derived Normal), aliquot ALCH-B1TH-NB1-A-1-0-D-A770-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4cf5130-556c-4961-a2b9-bd4ac4c2c0be

The open-access MAF lists 72 somatic variants for this specimen: 47 protein-altering or splice-affecting, 14 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 14, Intron 5, RNA 4, Nonsense Mutation 3, Frame Shift Ins 2, Splice Site 2, Frame Shift Del 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 132/391 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- C8A | c.770C>A p.A257D | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs1184523051; called by muse, mutect2, varscan2
- CELSR1 | c.4547C>T p.P1516L | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs766103727, COSV99416255; called by muse, mutect2
- COPS7B | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as rs756302127, COSV63115537; called by muse, mutect2, varscan2
- CRACD | c.2626G>A p.G876R | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201913634; called by muse, mutect2, varscan2
- DEFB113 | c.77G>T p.R26I | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.311); catalogued as COSV100435342, COSV59038094; called by muse, mutect2, varscan2
- F11 | c.803G>T p.R268L | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.035); catalogued as rs201688862, CM083501, COSV53007113; called by muse, mutect2, varscan2
- GHR | c.448G>C p.D150H | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50142547; called by muse, mutect2, varscan2
- GPKOW | c.947C>A p.T316N | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV99332693; called by muse, mutect2
- KIR3DL3 | c.1072C>A p.Q358K | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.816); catalogued as COSV52546724; called by muse, mutect2
- LRIG3 | c.2777C>T p.T926I | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.029); catalogued as rs775913390; called by muse, mutect2
- ODF3L2 | c.833G>T p.R278L | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV52748671; called by muse, mutect2, varscan2
- OR5L2 | c.248C>G p.A83G | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs1363923203; called by muse, mutect2
- RYR2 | c.8378G>T p.R2793L | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as COSV63674762; called by muse, mutect2, varscan2
- SAMHD1 | c.1410+1G>A p.X470_splice | Splice Site (SNP) | VAF 89/300 reads (30%) | catalogued as rs374561117; called by muse, mutect2, varscan2
- SAMSN1 | c.145C>G p.P49A | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99580583; called by muse, mutect2, varscan2
- SHISA6 | c.917C>A p.T306N (on ENST00000409168 / NM_001173461.1; = p.T357N on NM_207386.4) | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.116); catalogued as rs936371622; called by muse, mutect2, varscan2
- TP53 | c.461del p.G154Afs*16 | Frame Shift Del (DEL) | VAF 21/59 reads (36%) | catalogued as CM951223, COSV52667239, COSV52783646, COSV53625267; called by mutect2, pindel, varscan2
- ALDH18A1 | c.904A>G p.R302G | Missense Mutation (SNP) | VAF 51/316 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- AMIGO1 | c.1061T>A p.V354E | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CDH10 | c.1513C>A p.Q505K | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- CDX2 | c.419T>A p.L140H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- CELA1 | c.19C>A p.H7N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CROCC | c.1135A>T p.K379* | Nonsense Mutation (SNP) | VAF 21/135 reads (16%) | called by muse, mutect2, varscan2
- DBX2 | c.64C>A p.L22I | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.14); called by muse, mutect2
- DPYSL3 | c.962T>A p.L321Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ETV1 | c.1391del p.G464Afs*52 | Frame Shift Del (DEL) | VAF 54/207 reads (26%) | called by mutect2, pindel, varscan2
- FZD8 | c.774dup p.N259* | Frame Shift Ins (INS) | VAF 11/74 reads (15%) | called by mutect2, pindel, varscan2
- GALNT5 | c.1633G>A p.D545N | Missense Mutation (SNP) | VAF 13/238 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.242); called by muse, mutect2
- GTF3C5 | c.267G>T p.R89S | Missense Mutation (SNP) | VAF 25/244 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- KHDRBS2 | c.125A>T p.K42M | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2
- KIF24 | c.4103C>T p.S1368F | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- LILRB4 | c.533C>A p.A178D | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MSX1 | c.401C>A p.A134D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- MUL1 | c.791dup p.Q265Afs*19 | Frame Shift Ins (INS) | VAF 13/92 reads (14%) | called by mutect2, pindel, varscan2
- OBSCN | c.11189C>A p.T3730K | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- ORC1 | c.2101G>T p.E701* | Nonsense Mutation (SNP) | VAF 26/218 reads (12%) | called by muse, mutect2, varscan2
- PRADC1 | c.447-1_449del p.X149_splice | Splice Site (DEL) | VAF 9/90 reads (10%) | called by mutect2, pindel, varscan2
- PSMB3 | c.438G>T p.M146I | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2
- RNF225 | c.202G>T p.V68L | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- SAMD15 | c.571G>T p.G191W | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- SEL1L | c.2074G>A p.D692N | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- SLC9A3 | c.593C>G p.A198G | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- SNX18 | c.1498T>C p.Y500H | Missense Mutation (SNP) | VAF 5/109 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2
- STING1 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- TCF4 | c.147C>A p.C49* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- TGFB1I1 | c.595A>T p.T199S (on ENST00000394863 / NM_001042454.3; = p.T182S on NM_015927.4) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2
- CCNP | c.213G>T p.A71= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs748384706; called by muse, mutect2, varscan2
- FMNL2 | c.1194G>A p.L398= | Silent (SNP) | VAF 15/220 reads (7%) | called by muse, mutect2
- GJA8 | c.1164G>A p.S388= | Silent (SNP) | VAF 29/195 reads (15%) | catalogued as rs377042749, COSV99569424; called by muse, mutect2, varscan2
- GPC5 | c.564G>T p.L188= | Silent (SNP) | VAF 18/215 reads (8%) | called by muse, mutect2
- HSD17B14 | c.699C>T p.S233= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs930134447; called by muse, varscan2
- MYF6 | c.384G>T p.L128= | Silent (SNP) | VAF 23/117 reads (20%) | called by muse, mutect2, varscan2
- PCDHGA7 | c.300G>A p.A100= | Silent (SNP) | VAF 21/242 reads (9%) | catalogued as rs574670513, COSV53900574, COSV99544894; called by muse, mutect2
- PKD1L1 | c.8208C>T p.L2736= | Silent (SNP) | VAF 42/110 reads (38%) | catalogued as COSV99221767; called by muse, mutect2, varscan2
- PXDNL | c.3396T>A p.S1132= | Silent (SNP) | VAF 47/183 reads (26%) | called by muse, mutect2, varscan2
- SHISA6 | c.918C>A p.T306= (on ENST00000409168 / NM_001173461.1; = p.T357= on NM_207386.4) | Silent (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2, varscan2
- TOGARAM2 | c.1464G>A p.P488= | Silent (SNP) | VAF 29/154 reads (19%) | catalogued as rs764461123, COSV65420550; called by muse, mutect2, varscan2
- TXLNB | c.1648C>A p.R550= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV100624803; called by muse, mutect2, varscan2
- VARS2 | c.1890C>T p.V630= | Silent (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2, varscan2
- YIF1A | c.291G>T p.V97= | Silent (SNP) | VAF 13/131 reads (10%) | called by muse, mutect2, varscan2
- ALKBH5 | c.-298C>T | 5'UTR (SNP) | VAF 11/34 reads (32%) | catalogued as rs1204724192; called by muse, mutect2, varscan2
- ASH1L | c.5828+4490C>G | Intron (SNP) | VAF 14/402 reads (3%) | called by muse, mutect2
- ATP5MD | c.-9-1800C>G | Intron (SNP) | VAF 10/72 reads (14%) | catalogued as rs771139575; called by muse, mutect2, varscan2
- BAGE2 | n.282C>G | RNA (SNP) | VAF 28/594 reads (5%) | called by muse, mutect2
- DYNLRB1 | c.3+35G>A | Intron (SNP) | VAF 4/26 reads (15%) | called by muse, varscan2
- FBLN1 | c.1698-11450G>A | Intron (SNP) | VAF 8/72 reads (11%) | catalogued as rs1399088807; called by muse, mutect2, varscan2
- MIR411 | n.94G>T | RNA (SNP) | VAF 4/41 reads (10%) | called by mutect2, varscan2
- OR56B3P | n.73G>A | RNA (SNP) | VAF 30/142 reads (21%) | called by muse, mutect2
- OR56B3P | n.75C>A | RNA (SNP) | VAF 31/145 reads (21%) | called by muse, mutect2
- PDZD7 | c.-52G>T | 5'UTR (SNP) | VAF 10/98 reads (10%) | called by muse, varscan2
- SUPT20H | c.1592-961A>T | Intron (SNP) | VAF 9/116 reads (8%) | called by muse, mutect2
